Somatic mutation profile of tumor specimen TARGET-20-PASGAE-04A (aliquot TARGET-20-PASGAE-04A-01D) from TARGET case TARGET-20-PASGAE, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 0.9 years (322 days).
Specimen TARGET-20-PASGAE-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 790cd867-9ee9-4139-be6a-750cfaebb5f8.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASGAE-14A (Bone Marrow Normal), aliquot TARGET-20-PASGAE-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b0f658d-60cd-4dac-9951-411d2cf7e543

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.2782G>C p.E928Q | Missense Mutation (SNP) | VAF 130/275 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.575); catalogued as rs797044792; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCOR2 | c.7316G>A p.R2439Q | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.64); PolyPhen benign (0.283); catalogued as rs200604426; called by muse, varscan2
- SIGLEC1 | c.3889A>G p.N1297D | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs143389553; called by muse, mutect2, varscan2
- ACOT4 | c.564_569delinsTCAAAG p.A189_Y190delinsQS | Missense Mutation (ONP) | VAF 46/152 reads (30%) | called by pindel, varscan2*
- ARID1A | c.2879-39T>C | Intron (SNP) | VAF 97/197 reads (49%) | catalogued as rs552165524; called by muse, mutect2, varscan2
